Somatic mutation profile of tumor specimen C3N-01217-01 (aliquot CPT0076500006) from CPTAC case C3N-01217, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.3 years (21,296 days).
Specimen C3N-01217-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6d14c3f-dec5-44fa-969f-9a4ec20c9aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01217-71 (Blood Derived Normal), aliquot CPT0076580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404ccaee-7f9c-45c0-822a-5e2791e706d2

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Nonsense Mutation 6, Frame Shift Del 6, Intron 3, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/330 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as COSV50461413; called by muse, mutect2, varscan2
- EDIL3 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56884291; called by muse, mutect2
- GLDC | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 77/480 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as rs769035358; called by muse, mutect2, varscan2
- LRFN1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs748242195, COSV50492348; called by muse, mutect2, varscan2
- MYH7 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 87/415 reads (21%) | catalogued as rs761841748, COSV62521971; called by muse, mutect2, varscan2
- NEUROG3 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54342243; called by muse, mutect2
- PLA2G4E | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780660344; called by muse, mutect2, varscan2
- RBBP7 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV58113635; called by muse, mutect2, varscan2
- RERE | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 56/283 reads (20%) | catalogued as COSV100556546; called by muse, mutect2, varscan2
- SPTB | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs150063025, COSV67629736; called by muse, mutect2, varscan2
- TIGD3 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs769191642; called by muse, mutect2, varscan2
- ZNF226 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as rs771640806; called by muse, mutect2, varscan2
- ZNF418 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 65/352 reads (18%) | catalogued as rs563253023, COSV68676208; called by muse, mutect2, varscan2
- ADNP | c.254del p.F85Sfs*76 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel
- AGO4 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARFGEF1 | c.607A>C p.N203H | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ARID1A | c.6691_6707del p.M2231Rfs*41 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- ARID4A | c.3600_3627del p.Y1200* | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- CPA6 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GREB1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- MLPH | c.429_432del p.R144Cfs*9 | Frame Shift Del (DEL) | VAF 77/414 reads (19%) | called by mutect2, pindel, varscan2
- OR6C6 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIK3R1 | c.1169dup p.Y390* (on ENST00000521381 / NM_181523.3; = p.Y120* on NM_181504.4) | Nonsense Mutation (INS) | VAF 21/119 reads (18%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1729_1745+4del p.X577_splice (on ENST00000521381 / NM_181523.3; = p.X307_splice on NM_181504.4) | Splice Site (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- PTEN | c.757_758del p.I253Qfs*44 | Frame Shift Del (DEL) | VAF 102/346 reads (29%) | called by pindel, varscan2
- RCC2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RERE | c.338_339del p.I113Rfs*13 | Frame Shift Del (DEL) | VAF 28/217 reads (13%) | called by mutect2, pindel, varscan2
- SHOX | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIN3A | c.2696A>C p.H899P | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TOM1L1 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53BP1 | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TTN | c.54130G>T p.V18044F (on ENST00000591111; = p.V10620F on NM_003319.4) | Missense Mutation (SNP) | VAF 28/289 reads (10%) | PolyPhen benign (0.238); called by muse, mutect2
- DOCK4 | c.375G>A p.L125= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV101455501; called by muse, mutect2, varscan2
- DSCAM | c.1119T>C p.D373= | Silent (SNP) | VAF 40/323 reads (12%) | called by muse, mutect2, varscan2
- GGN | c.1128G>A p.P376= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1568391148; called by muse, mutect2, varscan2
- HIPK2 | c.240C>T p.Y80= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as rs375422566; called by muse, mutect2, varscan2
- MXRA5 | c.1581C>T p.D527= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- RIMBP3 | c.2751A>G p.Q917= | Silent (SNP) | VAF 92/769 reads (12%) | catalogued as rs542847264; called by muse, mutect2, varscan2
- RNF146 | c.273A>G p.P91= (on ENST00000368314 / NM_001242850.2; = p.P90= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- RTL8B | c.90C>T p.P30= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as rs1290064033; called by muse, mutect2
- SAFB | c.1359G>A p.T453= | Silent (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- SFMBT2 | c.2667C>T p.Y889= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs374897827; called by muse, mutect2, varscan2
- MGAM | c.4619-8718G>A | Intron (SNP) | VAF 47/405 reads (12%) | catalogued as rs768649204; called by muse, mutect2, varscan2
- OSBPL7 | c.1120-34C>T | Intron (SNP) | VAF 18/94 reads (19%) | catalogued as rs866891175; called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4684C>T | Intron (SNP) | VAF 52/240 reads (22%) | catalogued as COSV56507334; called by muse, mutect2, varscan2
- SLC11A2 | c.*1971G>A | 3'UTR (SNP) | VAF 24/125 reads (19%) | catalogued as rs563773129; called by muse, mutect2, varscan2
